Surgical pathology report (de-identified scan), TCGA case TCGA-2A-A8VX, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Memorial Sloan Kettering Cancer Center, specimen TCGA-2A-A8VX-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

Ref. Source:

....

Clinical Diagnosis & History:

Prostate cancer left anterior apex and right base.

Specimens Submitted:

- 1: Prostate and seminal vesicles, radical prostatectomy
- 2: Prostate at left base, biopsy
- 3: Peri-prostatic fat, biopsy
- 4: Right hypogastric lymph node, resection
- 5: Left pelvic lymph nodes, resection
- 6: Right pelvic lymph nodes, resection

ICD O-3
Adenocarcinoma, NOS 8140/3
Site: Prostate NOS C61.9
Q43/12/14

DIAGNOSIS:

1. Prostate and seminal vesicles, radical prostatectomy:

Part # 1

Tumor Type:

Adenocarcinoma

Gleason's Grade:

Primary Gleason grade:4

Secondary Gleason grade:4

A ductal/intraductal component is present. The dominant lesion is Gleason 4+4 = 8, but there is a significant 3 component.

Tumor Location:

Involves Right posterior

Involves Right anterior

Involves Left posterior

Involves Left anterior

Dominant tumor mass located in: Left anterior mid and right posterior mid

Vascular Invasion:

Not Identified

Perineural Invasion:

Identified

Tumor Multicentricity:

Multicentric foci of invasive carcinoma are present

High Grade Prostatic Intraepithelial Neoplasia:

Identified

Capsule:

Established extracapsular extension

The location of the extracapsular extension is Left anterior mid and right posterior mid to base

Seminal Vesicles:

Invades right seminal vesicle

Bladder Neck:

Not Involved

[page 2 of 5]
SURGICAL PATHOLOGY REPORT

Surgical Margins:

Free of tumor

Non-Neoplastic Prostate:

Unremarkable

Staging (AJCC 1997):

pT3b (invades seminal vesicle)

Comment: Immunohistochemistry for synaptophysin and chromogranin are negative.

2. **Prostate at left base, resection:**
- Benign seminal vesicle tissue with profound crush/ thermal artifact
3. **Peri-prostatic fat, resection:**
- Benign fibroadipose tissue and vessels
4. **Right hypogastric lymph node, resection:**
- Part # 4
- Lymph Node Dissection:
- Benign lymph nodes
- Number of lymph nodes examined: 3
- Number of lymph nodes with metastatic disease: 0
5. **Left pelvic lymph nodes, resection:**
- Part # 5
- Lymph Node Dissection:
- Benign lymph nodes
- Number of lymph nodes examined: 5
- Number of lymph nodes with metastatic disease: 0
6. **Right pelvic lymph nodes, resection:**
- Part # 6
- Lymph Node Dissection:
- Benign lymph nodes
- Number of lymph nodes examined: 8
- Number of lymph nodes with metastatic disease: 0

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as qualified to perform high complexity clinical laboratory testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

[page 3 of 5]
SURGICAL PATHOLOGY REPORT

Gross Description:

1) The specimen is received fresh, labeled "Prostate and seminal vesicles". It consists of a prostate and seminal vesicles. The total weight is 58.5 grams. The prostate measures 4.3cm from apex to base, 5.0cm transversely, and 3.7cm from anterior to posterior. The right and left seminal vesicles measure 3.5 x 1.3 and 4.0 x 1.5 cm, respectively. The external surface of the prostate is smooth. The prostate is inked (right=green, left=blue) and fixed in formalin overnight. The prostate is serially cut from apex to base at approximately 3-4 mm intervals. The prostate is entirely submitted.

Summary of Sections:

RA-right apical margin
LA-left apical margin
BN-bladder neck margin
RSV-right seminal vesicle
LSV-left seminal vesicle
A-H -serial sections of prostate (apex to base)

2) The specimen is received in formalin labeled, "prostate left base ", and consists of a 0.9 x 0.5 x 0.3 cm tan-pink piece of soft tissue . The specimen is entirely submitted.

Summary of sections:

U-- undesignated

3) The specimen is received in formalin labeled, "periprostic fat", and consists of multiple pieces of adipose tissue measuring 3.0 x 2.0 x 0.5 cm in aggregate. There is a 0.3 x 0.2 cm firm calcified nodule identified. The specimen is entirely submitted.

Summary of sections:

U-- undesignated
CN-calcified nodule

4) The specimen is received in formalin, labeled "right hypogastric lymph nodes", and consists of two firm lymph nodes. The largest measures 1.5 x 0.5 x 0.5 cm and the second lymph node 1.0 x 0.5 x 0.3 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

BLN - bisected largest lymph node
LN - lymph node

5) The specimen is received in formalin, labeled "left pelvic lymph nodes", and consists of 7x 6 x3 cm fatty tissue. Five pink tan firm lymph nodes ranging from one to four cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

SSL1-- serially sectioned lymph node #1
SSL2-- serially sectioned lymph node #2
SSL3-- serially sectioned lymph node #3
LN--two lymph nodes

[page 4 of 5]
SURGICAL PATHOLOGY REPORT

6).The specimen is received in formalin, labeled "right pelvic lymph nodes", and consists of 9 x 7 x 2 cm fatty tissue. Six possible lymph nodes identified ranging in size from 0.2 cm to 2.5 cm. All identified lymph nodes are submitted.

Summary of sections:

BLN - bisected lymph nodes

LN - lymph nodes

Summary of Sections:

Part 1: Prostate and seminal vesicles, radical prostatectomy

Blocks	Block Designation	PCs
1	A	1
1	B	1
1	BN	1
1	C	1
1	D	1
1	E	1
1	F	1
1	G	1
1	H	1
1	LA	1
1	LSV	1
1	RA	1
1	RSV	1

Part 2: Prostate at left base, biopsy

Blocks	Block Designation	PCs
1	U	2

Part 3: Peri-prostatic fat, biopsy

Blocks	Block Designation	PCs
1	CN	2
1	u	2

Part 4: Right hypogastric lymph node, resection

Blocks	Block Designation	PCs
1	BLN	2
1	LN	2

Part 5: Left pelvic lymph nodes, resection

Blocks	Block Designation	PCs
1	LN	2
2	SSL1	2
2	SSL2	3
2	SSL3	3

Part 6: Right pelvic lymph nodes, resection

Blocks	Block Designation	PCs
4	BLN	5
2	LN	3

Special Studies:

Result

Special Stain
RECUT

Comment

[page 5 of 5]
SURGICAL PATHOLOGY REPORT

RECUT
CHR
SYN
NEG CONT
IMM RECUT

Criteria	W 12/2/13	Yes	No
Dual/Synchronous Primary	Noted		✓

Source: NCI Genomic Data Commons file a4996da2-37ea-4826-8dc9-1cd072a35530 (TCGA-2A-A8VX.418E80EE-4886-43F5-9FB9-2619BC89351E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).